Somatic mutation profile of tumor specimen 0DRU3T from CCDI case PBCGTH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (428 days).
Specimen 0DRU3T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4298c7c-94ce-4d8d-bef8-ea12d1582402.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRU3N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/623d1392-0e4b-44ce-98fe-f314fb37c5c0

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPEB3 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1211150494, COSV56456831; called by muse, mutect2
- F2R | c.781A>T p.T261S | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.015); called by muse, mutect2
- TRAT1 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 179/994 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PNKD | c.236+1067C>T | Intron (SNP) | VAF 153/759 reads (20%) | catalogued as rs748457296, COSV99298191; called by muse, mutect2, varscan2
- SAG | c.181+26C>T | Intron (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
